Gene-level copy-number profile of tumor specimen ALCH-AE2O-TTP1-A from ALCHEMIST case ALCH-AE2O, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 75.8 years (27,684 days).
Specimen ALCH-AE2O-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b3dab980-2ccb-4649-ad12-4abdea0f639e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AE2O-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/43fbcf38-872b-4ebb-b4df-fc35c557ad71

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 1,840; copy number 2: 54,195; copy number 3: 2,316; copy number 4: 17; copy number 5: 16.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:158,469,586–158,470,702, 1 gene (within-gene range 0–2): AC121161.1.
- chr7:81,175,508–81,199,115, 2 genes (within-gene range 0–2): AC005008.2, AC005008.1.
- chr10:44,712–46,884, 1 gene: AL713922.1.
- chr11:116,829,706–116,837,622, 2 genes (within-gene range 0–2): APOC3, APOA1.
- chr16:15,125,242–15,154,564, 3 genes (within-gene range 0–2): PKD1P6, MIR6511B2, Y_RNA.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 16 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:18,333,726–18,419,273, 4 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr21:10,413,477–13,120,807, 12 genes, copy number 5: BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Autosomal genes at a single copy (total copy number 1): 1,592. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
